MMRF case MMRF_2827 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/c6f1d92d-b6e1-4780-9fe8-d6c3de0bb539

Demographics
Sex at birth: male; Age at index: 62 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; ISS stage: II; Days to last known disease status: 189 days; Days to last follow up: 189 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 191 days; Days to treatment end: 191 days.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy.

Follow-up (1 entry)
- Follow-up contacts recording only the day: day -8, day 189.

Molecular and laboratory tests (values rounded to 3 significant figures where GDC's unit conversion carried more)
- Lactate Dehydrogenase 3.68 µkat/L.
- Serum Free Immunoglobulin Light Chain, Kappa 0.857 mg/dL.
- Albumin 32.1 g/L.
- M Protein 7 g/dL.
- Serum Free Immunoglobulin Light Chain, Lambda 1.16 mg/dL.
- Beta 2 Microglobulin 0.66 µg/mL.
- Creatinine 123 µmol/L.
- Hemoglobin 5.58 mmol/L.
- Absolute Neutrophil 1.85 ×10⁹/L.
- Platelets 153 ×10⁹/L.
- Calcium 2.2 mmol/L.

Other clinical attributes
- Day -8: Weight: 76 kg; Height: 178 cm.

Biospecimens (2 samples)
- Sample MMRF_2827_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -8 days.
- Sample MMRF_2827_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -8 days.
